TCGA case TCGA-CV-5431 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/64bb5550-2735-4401-a0db-58ec1020a32d

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 73 years; Vital status: Dead; Days to death: 522 days (1.4 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 73.8 years (26,953 days); Year of diagnosis: 2000; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N2; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T3; AJCC pathologic N: N2c; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 9; Lymph nodes tested: 29; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 69 days; Treatment dose: 7,000 cGy; Number of fractions: 9; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 522 days (1.4 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking onset year: 1955; Tobacco smoking quit year: 1996.
- Alcohol history: Yes; Alcohol drinks per day: 2; Alcohol days per week: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CV-5431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-CV-5431-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50.
  Slide TCGA-CV-5431-01A-01-TS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60.
- Sample TCGA-CV-5431-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CV-5431-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; Days to last known alive: 176; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 4; Alcohol consumption frequency: 7.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 522 days; disease-specific survival: no event (censored), 522 days; progression-free interval: no event (censored), 522 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-CV-5431-01): tumor purity 0.35, ploidy 3.31, whole-genome doublings 1 (call status: legacy_maf_call).
